Surgical pathology report (de-identified scan), TCGA case TCGA-66-2777, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2777-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Middle lobe

Clinical diagnosis and question

Space-occupying lesion S4 right, squamous cell carcinoma with S4 bronchial obstruction; status post GIST rectum and urothelial carcinoma (6).

REPORT ON FINDINGS**Macroscopy**

- 1.) Middle lobe: inflated, fixed lobe of lung measuring 12 x 11 x 3.3 cm, central bronchus resection plane located 0.4 cm proximal to the bifurcation into the segmental bronchi and closed by a 6 cm long staple suture line running horizontally in a ventrodorsal direction. Similarly a 5 cm long staple suture line runs cranially to the hilus. At the hilus two partly lesioned blackish nodes, 1.3 and 0.4 cm in size. Pleura of partly turbid and cloudy appearance, irregular patches of blackish pigment with partially bloody coating or hemorrhagic patches over S4. Pleura over S4 shows slight central protrusion in an area of about 1 cm, central retraction and cranially a flat protrusion in an area of about 3 cm. Under this is a relatively firm, predominantly whitish, centrally grayish vitreous tumor, max. 3.2 cm in size, with partly blackish pigmentation, an arcuate demarcation, extending close to the visceral pleura with endobronchial growth in and obstruction of a subsegmental branch of B4; distance of endobronchial tumor growth from the bronchus resection plane about 0.9 cm. Tumor extending close to the staple suture line first described and separated from this by whitish hardened tissue. Other airways and rest of parenchyma inconspicuous, only vessels prominent and relatively dilated. Also in S5 a peripheral, subpleural compact area, max. 2 cm in size, section surfaces pale brownish, max. thickness 0.2 cm.
- 2.) Interlobar LN (station 11) right: 1 cm lesioned node or node part.
- 3.) Hilar LN (station 10) right: two lesioned nodes or node parts with some surrounding tissue, 0.6 and 0.2 cm.
- 4.) Subcarinal LN (station 7): 1.5 cm lesioned node or node part some surrounding tissue.

Examined:

- 1.) 1 section of tumor with immediately adjacent visceral pleura, 1 section of tumor with whitish area to first-named staple suture line (staple suture line marked green), 1 section of tumor with endobronchial tumor growth, described area in S5 peripheral (3 sections), bronchial and vascular resection margins (tangential) and also hilar nodes,
- 2.) - 4.) All material,
- 8 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Peripheral bronchopulmonary, large-cell and polymorphocellular, slightly keratinizing squamous cell carcinoma of middle lobe of lung (right). TNM classification according to this picture pT2 pN0 R0, stage IB. C 34,2; M 8070/3.

Secondary diagnosis/diagnoses:

Tumor-associated chronic inflammation and peripheral bronchitis. In part highly vascularized fibrosis of the visceral pleura covering the tumor with follicular chronic pleuritis. Perifocal cluster of alveolar pigmented macrophages. Slight emphysematous stromal remodeling and flat subpleural fibrous cicatricial zone of lung parenchyma. Slight to moderate anthracotic pigment deposits of lymph nodes with reactive macrophage cluster.

Remark/addendum:

The carcinoma lies in the subpleural region of S4, invasion of the pleura is not found in the samples examined. Centrally there is a connection between the tumor and the bronchial system, one intermediate branch of B4 being largely destroyed and obstructed by the tumor.

Source: NCI Genomic Data Commons file 62d0bdf9-7d21-4dee-ab10-0d44fc029b45 (TCGA-66-2777.32548C06-21B0-4A9C-A8B4-EAD02948D323.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).